Somatic mutation profile of tumor specimen TCGA-06-0878-01A (aliquot TCGA-06-0878-01A-01W-0424-08) from TCGA case TCGA-06-0878, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.8 years (27,319 days).
Specimen TCGA-06-0878-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e81efce4-de1d-4185-a547-00736ec3b8b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0878-10A (Blood Derived Normal), aliquot TCGA-06-0878-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52120fe0-d881-4d57-a0d0-904792697462

The open-access MAF lists 68 somatic variants for this specimen: 54 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Frame Shift Ins 21, Silent 13, Nonsense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYSF | c.4200dup p.I1401Hfs*8 | Frame Shift Ins (INS) | VAF 10/54 reads (19%) | catalogued as rs398123786; ClinVar: pathogenic; called by mutect2, varscan2
- LDLRAP1 | c.603dup p.S202Lfs*19 | Frame Shift Ins (INS) | VAF 8/40 reads (20%) | catalogued as rs781585299; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 32/220 reads (15%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ADAMTS20 | c.5216T>A p.I1739K | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV67132442; called by muse, mutect2, varscan2
- ALLC | c.620G>T p.C207F | Missense Mutation (SNP) | VAF 40/573 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs750179410, COSV52994908, COSV52996213; called by muse, mutect2
- AMY2B | c.1528A>C p.K510Q | Missense Mutation (SNP) | VAF 50/520 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63715421; called by muse, mutect2
- AXL | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs774132867, COSV56563807; called by muse, mutect2, varscan2
- BCL2L13 | c.428C>T p.T143I | Missense Mutation (SNP) | VAF 133/228 reads (58%) | SIFT tolerated (0.42); PolyPhen benign (0.037); catalogued as COSV58225968; called by muse, mutect2, varscan2
- CHD3 | c.1618dup p.R540Pfs*47 | Frame Shift Ins (INS) | VAF 40/352 reads (11%) | catalogued as rs747299117; called by mutect2, varscan2
- CHGB | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.031); catalogued as rs777454124, COSV66760679; called by muse, mutect2, varscan2
- CTNND2 | c.2997T>G p.D999E | Missense Mutation (SNP) | VAF 210/606 reads (35%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.97); catalogued as COSV58892489; called by muse, mutect2, varscan2
- DOCK2 | c.885G>T p.L295F | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as COSV56961207; called by muse, mutect2, varscan2
- ERCC1 | c.857T>C p.F286S | Missense Mutation (SNP) | VAF 85/209 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as rs1004869770, COSV50004329; called by muse, mutect2, varscan2
- GBP5 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs753752118, COSV58591452; called by muse, mutect2, varscan2
- GOLGA1 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs754268503, COSV65221247; called by muse, mutect2, varscan2
- HSPG2 | c.2275G>A p.G759S | Missense Mutation (SNP) | VAF 183/511 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65972199; called by muse, mutect2, varscan2
- ITGB6 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs751699169, COSV51794629; called by muse, mutect2, varscan2
- KBTBD6 | c.1326dup p.R443Afs*8 | Frame Shift Ins (INS) | VAF 27/155 reads (17%) | catalogued as rs774820321; called by mutect2, varscan2
- KLHL13 | c.335T>A p.M112K | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV53248434; called by muse, mutect2, varscan2
- KRTAP19-1 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as rs779790994, COSV66861263; called by muse, mutect2, varscan2
- KRTAP20-2 | c.144T>A p.Y48* | Nonsense Mutation (SNP) | VAF 66/167 reads (40%) | catalogued as COSV58183370; called by muse, mutect2, varscan2
- LAMB4 | c.2546G>A p.R849H | Missense Mutation (SNP) | VAF 109/461 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs148837121; called by muse, mutect2, varscan2
- LOXL3 | c.824dup p.A277Cfs*57 | Frame Shift Ins (INS) | VAF 16/62 reads (26%) | catalogued as rs746133895; called by mutect2, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 35/187 reads (19%) | catalogued as rs757410385; called by mutect2, varscan2
- MAP7D3 | c.922dup p.Q308Pfs*25 | Frame Shift Ins (INS) | VAF 18/160 reads (11%) | catalogued as rs746202015; called by mutect2, varscan2
- MMAA | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1390848245; called by muse, mutect2
- MYH3 | c.249dup p.K84Qfs*16 | Frame Shift Ins (INS) | VAF 29/219 reads (13%) | catalogued as rs761123152; called by mutect2, varscan2
- NAALADL1 | c.1243dup p.A415Gfs*2 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | catalogued as rs763799413; called by pindel, varscan2
- NCR1 | c.522G>C p.E174D | Missense Mutation (SNP) | VAF 154/441 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV52556827; called by muse, mutect2, varscan2
- NMBR | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 250/608 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs767510484, COSV57800816; called by mutect2, varscan2
- NRXN2 | c.808dup p.A270Gfs*27 | Frame Shift Ins (INS) | VAF 32/162 reads (20%) | catalogued as rs754860965; called by mutect2, varscan2
- NTHL1 | c.374dup p.V127Gfs*43 (on ENST00000219066; = p.V119Gfs*43 on NM_002528.7 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 10/74 reads (14%) | catalogued as rs763525759; called by mutect2, varscan2
- PDLIM3 | c.186dup p.E63Rfs*14 (on ENST00000284770 / NM_001257963.1; = p.E230Rfs*14 on NM_014476.6) | Frame Shift Ins (INS) | VAF 4/19 reads (21%) | catalogued as rs759971252; called by pindel, varscan2
- PPRC1 | c.2819dup p.P941Tfs*75 | Frame Shift Ins (INS) | VAF 26/154 reads (17%) | catalogued as rs768056539; called by mutect2, varscan2
- PRCC | c.1138dup p.Q380Pfs*12 | Frame Shift Ins (INS) | VAF 38/304 reads (13%) | catalogued as rs778683789; called by mutect2, varscan2
- PREX2 | c.4421G>A p.R1474K | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV55773414; called by muse, mutect2, varscan2
- ROBO2 | c.3233dup p.V1079Sfs*22 | Frame Shift Ins (INS) | VAF 43/213 reads (20%) | catalogued as rs745519558; called by mutect2, varscan2
- SBF1 | c.3228dup p.S1077Qfs*11 | Frame Shift Ins (INS) | VAF 18/162 reads (11%) | catalogued as rs771002611; called by mutect2, varscan2
- SCML2 | c.1360C>T p.H454Y | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV52621268; called by muse, mutect2
- SEMA3E | c.2009T>G p.L670W | Missense Mutation (SNP) | VAF 67/232 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57092315; called by muse, mutect2, varscan2
- SHC1 | c.1087dup p.V363Gfs*61 (on ENST00000368445 / NM_183001.5; = p.V253Gfs*62 on NM_003029.5) | Frame Shift Ins (INS) | VAF 50/225 reads (22%) | catalogued as rs746556543; called by mutect2, varscan2
- SPATA21 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs762700436; called by mutect2, varscan2
- TBC1D22A | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.545); catalogued as rs753108605, COSV61439874; called by muse, varscan2
- TBC1D22A | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.087); catalogued as rs752533977; called by muse, mutect2, varscan2
- TMPRSS6 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 54/81 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as rs1017672724, COSV100696262, COSV60978933; called by muse, mutect2, varscan2
- TRPM2 | c.529dup p.A177Gfs*92 | Frame Shift Ins (INS) | VAF 7/40 reads (18%) | catalogued as rs762935066; called by mutect2, varscan2
- USP6 | c.3752dup p.S1252Qfs*12 | Frame Shift Ins (INS) | VAF 22/214 reads (10%) | catalogued as rs754083634; called by mutect2, varscan2
- VMO1 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs1269286376, COSV99564567; called by muse, mutect2
- WDTC1 | c.868dup p.E290Gfs*7 | Frame Shift Ins (INS) | VAF 14/66 reads (21%) | catalogued as rs747972901; called by mutect2, varscan2
- ZNF692 | c.1059C>A p.H353Q | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60638025; called by muse, mutect2, varscan2
- CRYBG1 | c.2562G>T p.K854N | Missense Mutation (SNP) | VAF 34/1155 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.085); called by muse, mutect2
- DOCK3 | c.520C>A p.Q174K | Missense Mutation (SNP) | VAF 38/412 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.028); called by muse, mutect2
- IGHE | c.44G>C p.C15S | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- PLCG1 | c.2483G>A p.W828* | Nonsense Mutation (SNP) | VAF 36/295 reads (12%) | called by muse, mutect2, varscan2
- ATP2C2 | c.1017G>A p.L339= | Silent (SNP) | VAF 80/165 reads (48%) | catalogued as COSV52296650; called by muse, mutect2, varscan2
- COL9A3 | c.213G>A p.G71= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV59651977; called by muse, varscan2
- DNAH7 | c.1293C>T p.D431= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as rs370258473; called by muse, mutect2, varscan2
- GHRHR | c.1134C>T p.F378= | Silent (SNP) | VAF 25/388 reads (6%) | catalogued as rs1439938041, COSV58196649; called by muse, mutect2
- GLCCI1 | c.1305T>A p.R435= | Silent (SNP) | VAF 139/2999 reads (5%) | catalogued as COSV99780116; called by muse, mutect2
- HCRTR2 | c.891A>G p.R297= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV63796140; called by muse, mutect2, varscan2
- LPAR1 | c.174T>G p.T58= | Silent (SNP) | VAF 195/543 reads (36%) | catalogued as COSV62689031; called by muse, mutect2, varscan2
- NCKAP1L | c.1581C>T p.S527= | Silent (SNP) | VAF 120/300 reads (40%) | catalogued as rs559364211, COSV53207450; called by muse, mutect2, varscan2
- OR8H2 | c.516C>T p.N172= | Silent (SNP) | VAF 58/163 reads (36%) | catalogued as rs763293702, COSV57944151; called by muse, varscan2
- PCDHA8 | c.1611G>A p.A537= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV65327188; called by muse, mutect2, varscan2
- PPFIA2 | c.2745G>A p.A915= | Silent (SNP) | VAF 108/259 reads (42%) | catalogued as rs376356533; called by muse, mutect2, varscan2
- TMEM106B | c.420T>G p.R140= | Silent (SNP) | VAF 99/1440 reads (7%) | catalogued as rs140753733; called by muse, mutect2
- TRAF1 | c.576G>A p.G192= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs1057206846, COSV65868543, COSV65869151; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.*74dup | 3'UTR (INS) | VAF 25/239 reads (10%) | catalogued as rs747612913; called by mutect2, varscan2
